Somatic mutation profile of tumor specimen TCGA-23-1123-01A (aliquot TCGA-23-1123-01A-01W-0486-08) from TCGA case TCGA-23-1123, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 59.0 years (21,552 days).
Specimen TCGA-23-1123-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e75d16b-cc99-4acf-9881-8af300f247ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1123-10A (Blood Derived Normal), aliquot TCGA-23-1123-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf341c99-8901-488d-89f6-3593f5efc63b

The open-access MAF lists 83 somatic variants for this specimen: 70 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 11, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 2, Splice Region 1, Intron 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 112/156 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.650G>C p.R217P | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61361731; called by muse, mutect2, varscan2
- ADNP | c.2068G>A p.V690I | Missense Mutation (SNP) | VAF 118/439 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs370301614; called by muse, mutect2, varscan2
- AKNA | c.677C>G p.P226R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV56312429, COSV56312684; called by muse, mutect2, varscan2
- AOC2 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs142697203; called by muse, mutect2, varscan2
- ARHGAP35 | c.2255G>T p.S752I | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV68331456; called by muse, mutect2, varscan2
- BCLAF1 | c.1353T>A p.D451E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV62142277; called by muse, mutect2, varscan2
- BMPR2 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV65809538; called by muse, mutect2, varscan2
- CACNA1A | c.5872G>A p.V1958M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749251058, COSV64191850; called by muse, mutect2, varscan2
- CAMKV | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV56555431; called by muse, mutect2, varscan2
- CAMTA1 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs77267405, COSV57902082; called by muse, mutect2, varscan2
- CCDC148 | c.1423G>T p.V475L | Missense Mutation (SNP) | VAF 40/342 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV51760732; called by muse, mutect2, varscan2
- COL27A1 | c.5192G>T p.C1731F | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61926273; called by muse, mutect2, varscan2
- CPB1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 66/310 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs766816862, COSV51573302; called by muse, mutect2, varscan2
- CPEB1 | c.509C>A p.P170H (on ENST00000617958; = p.P110H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/377 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55619003; called by muse, mutect2, varscan2
- CUX2 | c.3727G>C p.G1243R | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV55632710; called by muse, mutect2, varscan2
- DGAT2L6 | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 142/311 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV60717817; called by muse, mutect2, varscan2
- DPP10 | c.1074+1G>A p.X358_splice | Splice Site (SNP) | VAF 14/50 reads (28%) | catalogued as COSV59687573; called by muse, mutect2, varscan2
- ENAM | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 205/485 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV101252877; called by muse, mutect2, varscan2
- EPS15L1 | c.2192G>C p.G731A | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV50168993; called by muse, mutect2, varscan2
- FAM171B | c.2285A>C p.H762P | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV59003718; called by muse, mutect2, varscan2
- FBXL7 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs760845839, COSV61644189; called by muse, mutect2, varscan2
- FGD4 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV56783994; called by muse, mutect2, varscan2
- FH | c.1325C>G p.T442R | Missense Mutation (SNP) | VAF 86/428 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1060500899, COSV63818212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FIGNL1 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63553520; called by muse, mutect2, varscan2
- FMN2 | c.2425C>A p.Q809K | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV60418843, COSV60431060; called by muse, mutect2, varscan2
- GC | c.554T>C p.M185T | Missense Mutation (SNP) | VAF 52/564 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56737443; called by muse, mutect2
- GNAS | c.489C>G p.Y163* | Nonsense Mutation (SNP) | VAF 44/320 reads (14%) | catalogued as CM002274, COSV55677028; called by muse, mutect2, varscan2
- HEPACAM2 | c.714T>A p.Y238* (on ENST00000394468 / NM_001039372.4; = p.Y226* on NM_198151.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 58/190 reads (31%) | catalogued as COSV59060502; called by muse, mutect2, varscan2
- IFNA5 | c.329C>G p.T110S | Missense Mutation (SNP) | VAF 116/286 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as COSV52386873; called by muse, mutect2, varscan2
- KIF17 | c.2889C>A p.S963R | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV56118302; called by muse, mutect2, varscan2
- LYST | c.3624G>T p.Q1208H | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV67707157; called by muse, mutect2, varscan2
- MAN2B1 | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54418341; called by muse, mutect2, varscan2
- MMP13 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 111/381 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.049); catalogued as rs781966264, COSV52824119; called by muse, mutect2, varscan2
- MYO1F | c.45G>C p.K15N | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV57795300; called by muse, mutect2, varscan2
- NCF2 | c.448A>G p.M150V | Missense Mutation (SNP) | VAF 118/550 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs1340153036, COSV62315564; called by muse, mutect2, varscan2
- NUP160 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs772355663, COSV65854444; called by muse, mutect2, varscan2
- NXPE4 | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100970279; called by muse, mutect2
- OR2AK2 | c.21T>A p.S7R | Missense Mutation (SNP) | VAF 148/703 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV63553053; called by muse, mutect2, varscan2
- OR5AK2 | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 360/1343 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV58804503; called by muse, mutect2, varscan2
- PABPC5 | c.437G>C p.G146A | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57040952; called by muse, mutect2, varscan2
- PLCB4 | c.1858A>G p.S620G | Missense Mutation (SNP) | VAF 32/774 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99593943; called by muse, mutect2
- PLCXD3 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 71/231 reads (31%) | catalogued as COSV60609020; called by muse, mutect2, varscan2
- PNISR | c.647del p.P216Lfs*2 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as COSV65079252; called by mutect2, pindel, varscan2
- PNP | c.602A>T p.E201V | Missense Mutation (SNP) | VAF 49/466 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64091972; called by muse, mutect2, varscan2
- POTED | c.452A>G p.K151R | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as COSV55048268; called by muse, mutect2, varscan2
- PRSS53 | c.108dup p.K37Qfs*44 | Frame Shift Ins (INS) | VAF 4/8 reads (50%) | catalogued as rs759089621; called by mutect2, varscan2
- PTPRO | c.1654A>G p.R552G | Missense Mutation (SNP) | VAF 196/827 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV99839416; called by muse, mutect2, varscan2
- REP15 | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs781501132, COSV57291892; called by muse, mutect2, varscan2
- RRH | c.955G>C p.V319L | Missense Mutation (SNP) | VAF 125/399 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV58491493, COSV58491931; called by muse, mutect2, varscan2
- SFXN1 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV58493426; called by muse, mutect2, varscan2
- SMARCA4 | c.2441C>A p.T814K | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60792950, COSV60795041; called by muse, mutect2, varscan2
- SOX6 | c.1834C>T p.R612C (on ENST00000528429 / NM_001145819.2; = p.R585C on NM_017508.3) | Missense Mutation (SNP) | VAF 86/285 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1434670578, COSV57035391; called by muse, mutect2, varscan2
- THSD7B | c.1976C>A p.S659Y | Missense Mutation (SNP) | VAF 73/335 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV55688410; called by muse, mutect2, varscan2
- TMEM248 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 390/852 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV100447449, COSV58577462; called by muse, varscan2
- TRAPPC12 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201978278, COSV60847696; called by muse, mutect2, varscan2
- TRIM67 | c.1720G>A p.G574S | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs1424485115, COSV100792244, COSV64158114; called by muse, mutect2, varscan2
- TROAP | c.1718A>G p.E573G | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV57744230; called by muse, varscan2
- TULP1 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV57692653; called by muse, mutect2, varscan2
- UBAP2L | c.1449G>C p.Q483H | Missense Mutation (SNP) | VAF 34/344 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.979); catalogued as COSV55173039; called by muse, mutect2, varscan2
- UIMC1 | c.1676+1G>A p.X559_splice | Splice Site (SNP) | VAF 78/294 reads (27%) | catalogued as rs766653801, COSV65893601; called by muse, mutect2, varscan2
- VCAN | c.5395T>A p.L1799I | Missense Mutation (SNP) | VAF 63/96 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as COSV54105510; called by muse, mutect2, varscan2
- ZC4H2 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 125/244 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as rs1490919537, COSV62003530, COSV62005568; called by muse, mutect2, varscan2
- ZMAT1 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 138/436 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV65658630; called by muse, mutect2, varscan2
- ZNF182 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 82/657 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1556898382, COSV59357357; called by muse, mutect2, varscan2
- ZNF285 | c.80A>G p.K27R | Missense Mutation (SNP) | VAF 141/344 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.49); catalogued as COSV58409077; called by muse, mutect2, varscan2
- ZNF793 | c.862dup p.C288Lfs*28 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | catalogued as rs761241629; called by mutect2, varscan2
- ZNFX1 | c.3538A>G p.R1180G | Missense Mutation (SNP) | VAF 155/936 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV65597825; called by muse, mutect2, varscan2
- MDS2 | n.734C>A | Splice Region (SNP) | VAF 28/138 reads (20%) | called by muse, mutect2, varscan2
- SPIDR | c.438C>G p.D146E | Missense Mutation (SNP) | VAF 148/781 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ADGRE3 | c.783T>C p.D261= | Silent (SNP) | VAF 56/307 reads (18%) | catalogued as COSV53730731; called by muse, mutect2, varscan2
- AFP | c.765C>T p.I255= | Silent (SNP) | VAF 161/1103 reads (15%) | catalogued as COSV56925306; called by muse, mutect2, varscan2
- AP3B2 | c.2727C>A p.I909= (on ENST00000261722; = p.I903= on NM_004644.5) | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV55609808, COSV55612153; called by muse, mutect2, varscan2
- CRACR2A | c.708C>A p.L236= | Silent (SNP) | VAF 250/597 reads (42%) | catalogued as COSV52913089; called by muse, mutect2, varscan2
- JCAD | c.3303G>A p.P1101= | Silent (SNP) | VAF 95/372 reads (26%) | catalogued as rs1311204726, COSV64759711; called by muse, mutect2, varscan2
- P4HA1 | c.729T>A p.G243= | Silent (SNP) | VAF 36/161 reads (22%) | catalogued as COSV54961644; called by muse, mutect2, varscan2
- PKP4 | c.1008G>A p.S336= | Silent (SNP) | VAF 121/233 reads (52%) | catalogued as rs200934987, COSV67677182; called by muse, mutect2, varscan2
- PPFIBP2 | c.1347C>T p.D449= | Silent (SNP) | VAF 39/238 reads (16%) | catalogued as rs765647290, COSV55077230; called by muse, mutect2, varscan2
- QRICH1 | c.2094A>G p.P698= | Silent (SNP) | VAF 41/153 reads (27%) | catalogued as COSV58707960; called by muse, mutect2, varscan2
- STARD5 | c.534C>A p.T178= | Silent (SNP) | VAF 76/399 reads (19%) | catalogued as COSV100250949, COSV57154928; called by muse, mutect2, varscan2
- XPO1 | c.763C>T p.L255= | Silent (SNP) | VAF 28/238 reads (12%) | catalogued as COSV101294187, COSV68946036; called by muse, varscan2
- LMNA | c.357-3720C>T | Intron (SNP) | VAF 9/44 reads (20%) | catalogued as rs760318158, COSV61543001; called by muse, mutect2, varscan2
- VAX1 | chr10:117132237 G>T | 3'Flank (SNP) | VAF 10/27 reads (37%) | catalogued as COSV53328674, COSV53329131; called by muse, mutect2, varscan2
